Somatic mutation profile of tumor specimen TARGET-20-PASTSH-09A (aliquot TARGET-20-PASTSH-09A-01D) from TARGET case TARGET-20-PASTSH, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 12.7 years (4,650 days).
Specimen TARGET-20-PASTSH-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fec2800e-a3db-422e-bd07-d6d7da1726af.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASTSH-14A (Bone Marrow Normal), aliquot TARGET-20-PASTSH-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1a305193-3231-418d-92e4-6313b1fb8214

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CEBPA | c.247C>T p.Q83* | Nonsense Mutation (SNP) | VAF 14/47 reads (30%) | catalogued as COSV57200140; called by muse, varscan2
- SMC3 | c.1928C>A p.A643D | Missense Mutation (SNP) | VAF 13/267 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
